Somatic mutation profile of tumor specimen MP2PRT-PAVFVG-TMP1-A (aliquot MP2PRT-PAVFVG-TMP1-A-1-0-D-A79Q-36) from MP2PRT case MP2PRT-PAVFVG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,110 days).
Specimen MP2PRT-PAVFVG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01d73740-4f7d-46dc-ac18-b8e84539578b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVFVG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVFVG-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3675826-e330-477f-ad61-f94dc0e24f20

The open-access MAF lists 82 somatic variants for this specimen: 63 protein-altering or splice-affecting, 12 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 12, Nonsense Mutation 7, Intron 3, Splice Region 1, 3'Flank 1, 5'Flank 1, RNA 1, Frame Shift Del 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAP3 | c.758C>G p.S253C | Missense Mutation (SNP) | VAF 110/293 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs1160420340, COSV100686758; called by muse, mutect2, varscan2
- ACP1 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 160/431 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.263); catalogued as rs1130615; called by muse, varscan2
- BRD8 | c.2343G>C p.Q781H (on ENST00000254900 / NM_139199.2; = p.Q854H on NM_006696.4) | Missense Mutation (SNP) | VAF 127/357 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1310842146; called by muse, mutect2, varscan2
- BRIP1 | c.3521G>C p.R1174T | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.199); catalogued as rs786202662, COSV51996620; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD14 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 153/412 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); catalogued as rs755997839, COSV57370722; called by muse, mutect2, varscan2
- CDH8 | c.1576A>G p.K526E | Missense Mutation (SNP) | VAF 111/271 reads (41%) | SIFT tolerated (0.62); PolyPhen benign (0.103); catalogued as COSV54861581, COSV54885299; called by muse, mutect2, varscan2
- CHST13 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 148/466 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.821); catalogued as rs1167136138; called by muse, varscan2
- ETNPPL | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 94/271 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV56597123; called by muse, mutect2, varscan2
- LATS1 | c.721C>G p.Q241E | Missense Mutation (SNP) | VAF 165/350 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.542); catalogued as rs769758085; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 119/318 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR8J3 | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 77/221 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs550603090, COSV56879225; called by muse, mutect2, varscan2
- PCDHGA4 | c.1966G>C p.E656Q | Missense Mutation (SNP) | VAF 153/429 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV99534004; called by muse, mutect2, varscan2
- PCLO | c.12439C>G p.H4147D | Missense Mutation (SNP) | VAF 15/375 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.387); catalogued as COSV61643160; called by muse, mutect2
- PEAR1 | c.2852C>G p.S951* | Nonsense Mutation (SNP) | VAF 15/547 reads (3%) | catalogued as COSV52772312; called by muse, mutect2
- RAF1 | c.1928C>T p.P643L | Missense Mutation (SNP) | VAF 118/322 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs1382398408; ClinVar: uncertain significance; called by muse, varscan2
- RBM22 | c.1069C>A p.P357T | Missense Mutation (SNP) | VAF 170/392 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV52272958; called by muse, mutect2, varscan2
- RIMS1 | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 16/404 reads (4%) | catalogued as COSV53451570; called by muse, mutect2
- ST18 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 130/318 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV52508400; called by muse, varscan2
- THY1 | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 91/266 reads (34%) | catalogued as rs551221908; called by muse, mutect2, varscan2
- TLE2 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 90/261 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as rs1018382206, COSV53579712; called by muse, mutect2, varscan2
- TMEM132C | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 155/428 reads (36%) | catalogued as rs1398496122; called by muse, mutect2, varscan2
- TMX3 | c.1073G>A p.R358K | Missense Mutation (SNP) | VAF 40/217 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs991939128; called by muse, mutect2, varscan2
- ZNF451 | c.2995C>T p.H999Y (on ENST00000370706 / NM_001031623.3; = p.H951Y on NM_015555.2) | Missense Mutation (SNP) | VAF 139/424 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.855); catalogued as rs1427489333; called by muse, mutect2, varscan2
- AC242842.3 | c.304C>G p.Q102E | Missense Mutation (SNP) | VAF 106/166 reads (64%) | SIFT tolerated (0.06); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ADAM21 | c.1024G>C p.E342Q | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- BBX | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 95/249 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- BCHE | c.673G>C p.E225Q | Missense Mutation (SNP) | VAF 12/398 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2
- C19orf18 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 101/266 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, varscan2
- C2orf16 | c.1354G>C p.E452Q | Missense Mutation (SNP) | VAF 95/288 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CARD17 | c.42C>G p.I14M | Missense Mutation (SNP) | VAF 72/230 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, varscan2
- CELA3B | c.407G>T p.G136V | Missense Mutation (SNP) | VAF 195/502 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- CENPB | c.1780G>A p.G594S | Missense Mutation (SNP) | VAF 67/212 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CFAP47 | c.3601G>A p.E1201K | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT tolerated (0.82); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CHD8 | c.5038G>C p.D1680H (on ENST00000646647 / NM_001170629.2; = p.D1401H on NM_020920.4) | Missense Mutation (SNP) | VAF 67/175 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- DAB1 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 105/310 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- DCBLD1 | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 209/621 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DGAT2L6 | c.519G>C p.Q173H | Missense Mutation (SNP) | VAF 192/492 reads (39%) | SIFT tolerated (0.93); PolyPhen benign (0.01); called by muse, varscan2
- EXTL2 | c.721C>G p.Q241E | Missense Mutation (SNP) | VAF 103/304 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- FRMD4B | c.1271G>C p.R424T | Missense Mutation (SNP) | VAF 12/302 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2
- GRIN2A | c.1327_1328+2del p.X443_splice | Splice Site (DEL) | VAF 58/181 reads (32%) | called by mutect2, pindel, varscan2
- GRM8 | c.2048C>G p.S683C | Missense Mutation (SNP) | VAF 135/350 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.215); called by muse, varscan2
- HADHA | c.41C>G p.S14C | Missense Mutation (SNP) | VAF 176/406 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HDAC7 | c.1904C>G p.S635C (on ENST00000427332; = p.S674C on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 138/330 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- HSPA12B | c.1912G>A p.D638N | Missense Mutation (SNP) | VAF 242/603 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- KANSL1 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 120/368 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MEIOC | c.100C>A p.R34S | Missense Mutation (SNP) | VAF 140/380 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- MOB1A | c.373C>T p.Q125* | Nonsense Mutation (SNP) | VAF 73/216 reads (34%) | called by muse, varscan2
- MTBP | c.2260G>A p.E754K | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- NDUFB10 | c.274_281del p.V92Rfs*92 | Frame Shift Del (DEL) | VAF 80/218 reads (37%) | called by mutect2, pindel, varscan2
- NFRKB | c.196C>G p.Q66E (on ENST00000446488 / NM_001143835.2; = p.Q79E on NM_006165.3) | Missense Mutation (SNP) | VAF 17/438 reads (4%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.952); called by muse, mutect2
- OR7G2 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 155/428 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- PCDHB12 | c.2175C>A p.C725* | Nonsense Mutation (SNP) | VAF 200/570 reads (35%) | called by muse, mutect2, varscan2
- PCNT | c.3265G>C p.E1089Q | Missense Mutation (SNP) | VAF 124/339 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- PEX14 | c.489G>A p.V163= | Splice Region (SNP) | VAF 96/280 reads (34%) | called by muse, mutect2, varscan2
- PIAS1 | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 93/240 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- RFX3 | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 168/396 reads (42%) | called by muse, mutect2, varscan2
- SEPTIN7 | c.253C>T p.H85Y | Missense Mutation (SNP) | VAF 75/238 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SPATA31D1 | c.2032C>G p.P678A | Missense Mutation (SNP) | VAF 31/747 reads (4%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.969); called by muse, mutect2
- TAS2R5 | c.46G>C p.E16Q | Missense Mutation (SNP) | VAF 126/333 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEX15 | c.105G>C p.L35F (on ENST00000638951; = p.L31F on NM_001350162.2) | Missense Mutation (SNP) | VAF 113/263 reads (43%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- THBS1 | c.1676G>A p.G559D | Missense Mutation (SNP) | VAF 132/292 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM67 | c.2415G>C p.M805I | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZNF727 | c.1282G>C p.E428Q | Missense Mutation (SNP) | VAF 119/347 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.602); called by muse, varscan2
- BRS3 | c.1197C>T p.F399= | Silent (SNP) | VAF 136/331 reads (41%) | called by muse, mutect2, varscan2
- FAM114A2 | c.699G>A p.K233= | Silent (SNP) | VAF 142/354 reads (40%) | catalogued as COSV61076934; called by muse, mutect2, varscan2
- HSPA12A | c.342C>T p.F114= | Silent (SNP) | VAF 21/464 reads (5%) | catalogued as rs374384405; called by muse, mutect2
- MAGI1 | c.3798G>A p.P1266= | Silent (SNP) | VAF 183/491 reads (37%) | catalogued as rs1329036742; called by muse, mutect2, varscan2
- MED12L | c.2508C>T p.L836= | Silent (SNP) | VAF 126/340 reads (37%) | catalogued as COSV56367100; called by muse, mutect2, varscan2
- NKAPL | c.249C>T p.F83= | Silent (SNP) | VAF 148/400 reads (37%) | called by muse, mutect2, varscan2
- PLIN4 | c.2664C>G p.L888= (on ENST00000301286; = p.L903= on NM_001367868.2) | Silent (SNP) | VAF 209/641 reads (33%) | called by muse, mutect2, varscan2
- SYNE2 | c.19800G>A p.L6600= | Silent (SNP) | VAF 82/246 reads (33%) | called by muse, mutect2, varscan2
- TENM1 | c.2886G>A p.E962= | Silent (SNP) | VAF 169/491 reads (34%) | catalogued as rs752816390; called by muse, mutect2, varscan2
- TENM3 | c.3339C>A p.G1113= | Silent (SNP) | VAF 17/409 reads (4%) | called by muse, mutect2
- TPD52L1 | c.534C>A p.V178= | Silent (SNP) | VAF 135/322 reads (42%) | catalogued as rs534330998; called by muse, mutect2, varscan2
- ZC3H12B | c.1665G>A p.L555= | Silent (SNP) | VAF 175/462 reads (38%) | called by muse, varscan2
- DIABLO | c.305-1247C>G | Intron (SNP) | VAF 121/308 reads (39%) | called by muse, varscan2
- GCNT2 | c.926-34630G>A | Intron (SNP) | VAF 156/345 reads (45%) | catalogued as COSV53943007; called by muse, mutect2, varscan2
- LHX6 | chr9:122228680 C>G | 5'Flank (SNP) | VAF 204/500 reads (41%) | called by muse, mutect2
- Metazoa_SRP | chr5:91314304 G>C | 3'Flank (SNP) | VAF 134/301 reads (45%) | called by muse, mutect2, varscan2
- PROZ | c.70+493G>T | Intron (SNP) | VAF 25/586 reads (4%) | called by muse, mutect2
- SLC22A17 | n.736G>A | RNA (SNP) | VAF 16/506 reads (3%) | called by muse, mutect2
- SNAP29 | c.*2466C>T | 3'UTR (SNP) | VAF 131/383 reads (34%) | called by muse, mutect2, varscan2
